Somatic mutation profile of tumor specimen MP2PRT-PASLDF-TMP1-B (aliquot MP2PRT-PASLDF-TMP1-B-1-0-D-A817-36) from MP2PRT case MP2PRT-PASLDF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,889 days).
Specimen MP2PRT-PASLDF-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05991c13-4556-48b6-9ee2-4259255d5cf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLDF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLDF-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3debd508-5be6-4f78-a468-7bb57e61720e

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.5744C>T p.A1915V | Missense Mutation (SNP) | VAF 66/500 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375547019; called by muse, mutect2, varscan2
- CSPG4 | c.3100C>T p.R1034W | Missense Mutation (SNP) | VAF 73/506 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs770213957; called by muse, mutect2, varscan2
- LRRC72 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 181/403 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs957689009, COSV66127324; called by muse, mutect2, varscan2
- MGAT4C | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 150/370 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs140499591; called by muse, varscan2
- MYH14 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 218/504 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as rs1316683575, COSV51826644; called by muse, mutect2, varscan2
- PAX5 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 122/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63908111; called by muse, mutect2, varscan2
- NPR1 | c.1936-1G>A p.X646_splice | Splice Site (SNP) | VAF 112/241 reads (46%) | called by muse, mutect2, varscan2
- CFAP43 | c.3273G>T p.P1091= | Silent (SNP) | VAF 134/346 reads (39%) | called by muse, varscan2
- KIF16B | c.3498+3020G>A | Intron (SNP) | VAF 18/452 reads (4%) | called by muse, mutect2
- NRK | c.4354-887C>T | Intron (SNP) | VAF 9/198 reads (5%) | catalogued as COSV54599703; called by muse, mutect2
